Somatic mutation profile of tumor specimen TARGET-40-NAAHDI-01A (aliquot TARGET-40-NAAHDI-01A-01D) from TARGET case TARGET-40-NAAHDI, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.6 years (5,705 days).
Specimen TARGET-40-NAAHDI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 941a973e-72cc-44da-9c7b-25319725316b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHDI-10A (Blood Derived Normal), aliquot TARGET-40-NAAHDI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aca1ed1c-3421-44a3-80bf-62b1779b5a5f

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN5 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs772226535, COSV54360366; called by muse, varscan2
- ANK3 | c.10808T>G p.F3603C | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCL6 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CNTNAP5 | c.3040G>T p.E1014* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | called by mutect2, varscan2
- FER1L6 | c.1636G>T p.D546Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2
- HDAC1 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.515); called by muse, mutect2
- TTN | c.6312A>T p.K2104N (on ENST00000591111; = p.K2058N on NM_003319.4) | Missense Mutation (SNP) | VAF 18/256 reads (7%) | PolyPhen possibly damaging (0.526); called by muse, mutect2
- FER1L6 | c.1329T>G p.T443= | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
